Somatic mutation profile of tumor specimen TCGA-24-2271-01A (aliquot TCGA-24-2271-01A-01W-0799-08) from TCGA case TCGA-24-2271, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.8 years (20,399 days).
Specimen TCGA-24-2271-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 327f63d3-deaf-470c-a22f-6714b5a42048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2271-10A (Blood Derived Normal), aliquot TCGA-24-2271-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ec6c011-e8c9-48dc-9192-0726a4c4e49a

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 8, In Frame Del 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 42/217 reads (19%) | catalogued as COSV100008268; called by muse, mutect2, varscan2
- ASTN2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs1296659562, COSV57748006, COSV57776763; called by muse, varscan2
- C7 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as rs1393459238, COSV57476232; called by muse, varscan2
- CARD14 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs776782295, COSV60126887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC80 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV99245068; called by muse, mutect2
- CCL28 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 135/530 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs1242216229, COSV63149322, COSV63150163; called by muse, mutect2, varscan2
- CNKSR2 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 25/381 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99669288; called by muse, mutect2
- COL11A1 | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV62198039; called by muse, mutect2, varscan2
- CREB3L1 | c.1029C>T p.N343= | Splice Region (SNP) | VAF 7/13 reads (54%) | catalogued as COSV55833149, COSV55833195; called by muse, mutect2, varscan2
- CRYBB3 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 12/356 reads (3%) | catalogued as COSV99309148; called by muse, mutect2
- CTSL | c.350del p.S117Lfs*10 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as COSV58247528; called by mutect2, pindel, varscan2
- DNAH10 | c.8773C>T p.H2925Y (on ENST00000409039; = p.H2864Y on NM_207437.3) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1349651534; called by muse, mutect2
- DNAH10 | c.8774A>G p.H2925R (on ENST00000409039; = p.H2864R on NM_207437.3) | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1205684113, COSV68991735; called by muse, mutect2
- FIG4 | c.2523G>T p.R841S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV57791518; called by muse, mutect2
- FRMPD3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs371922832, COSV99346780; called by muse, mutect2, varscan2
- FSIP2 | c.17074T>C p.S5692P | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100555789; called by muse, mutect2, varscan2
- HIPK1 | c.2711G>T p.S904I | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100479453; called by muse, mutect2
- ITGA9 | c.2396T>G p.L799R | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.102); catalogued as COSV53237433, COSV99293465; called by muse, mutect2, varscan2
- KIAA0232 | c.2687G>T p.R896I | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV100300969; called by muse, mutect2
- PCDH18 | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as rs774437643, COSV61272242; called by muse, mutect2, varscan2
- PJA1 | c.1889G>T p.G630V (on ENST00000361478 / NM_145119.4; = p.G442V on NM_022368.5) | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64053054, COSV64053786; called by muse, mutect2, varscan2
- PPM1F | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54286672; called by muse, mutect2, varscan2
- PPP2CA | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 61/164 reads (37%) | catalogued as COSV51537621; called by muse, mutect2, varscan2
- PRKCG | c.1477C>A p.H493N | Missense Mutation (SNP) | VAF 10/324 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99669314; called by muse, mutect2
- PRUNE2 | c.6574C>A p.P2192T | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100944925; called by muse, mutect2
- RAG1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100201046; called by muse, mutect2
- RHOG | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); catalogued as COSV53463868, COSV99544481; called by muse, mutect2, varscan2
- SAP30L | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV99770446; called by mutect2, varscan2
- SCN7A | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 103/472 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV101313248, COSV69270986; called by muse, mutect2
- SEC16B | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 14/280 reads (5%) | catalogued as COSV100381795; called by muse, mutect2
- STX16 | c.886C>T p.Q296* (on ENST00000371141 / NM_001001433.3; = p.Q275* on NM_003763.6) | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV56608396; called by muse, mutect2, varscan2
- TEX13A | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100782221, COSV61183333; called by muse, mutect2, varscan2
- TIAM2 | c.1224C>A p.Y408* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100019633; called by muse, mutect2
- TP53 | c.961A>T p.K321* | Nonsense Mutation (SNP) | VAF 82/163 reads (50%) | catalogued as COSV52686338, COSV52850306; called by muse, mutect2, varscan2
- WDR59 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1160200273, COSV50934817; called by muse, mutect2, varscan2
- ZNF227 | c.1174A>G p.S392G | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV57313719; called by muse, mutect2, varscan2
- ZNF41 | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 86/457 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100492194; called by muse, mutect2, varscan2
- RNF2 | c.204_212del p.L68_R70del | In Frame Del (DEL) | VAF 168/781 reads (22%) | called by mutect2, pindel, varscan2
- C12orf40 | c.942G>A p.R314= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV61132688; called by muse, mutect2, varscan2
- CD22 | c.879G>A p.T293= | Silent (SNP) | VAF 58/176 reads (33%) | catalogued as rs781077986, COSV50069427; called by muse, mutect2, varscan2
- CNTNAP5 | c.2373C>T p.N791= | Silent (SNP) | VAF 102/354 reads (29%) | catalogued as rs566175180, COSV70474787; called by muse, mutect2, varscan2
- DUXA | c.498G>A p.A166= | Silent (SNP) | VAF 21/226 reads (9%) | catalogued as rs370297842; called by muse, mutect2
- HECW1 | c.732C>A p.L244= | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV101224085; called by muse, mutect2
- KDM3B | c.1065C>A p.R355= | Silent (SNP) | VAF 56/710 reads (8%) | catalogued as COSV100070004; called by muse, mutect2
- MUC16 | c.34455A>G p.P11485= | Silent (SNP) | VAF 67/1740 reads (4%) | catalogued as COSV101200595; called by muse, mutect2
- SIGLEC11 | c.1008G>A p.A336= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as rs750459116, COSV101389042, COSV70222174; called by muse, mutect2, varscan2
- TDRD5 | c.1728C>T p.F576= | Silent (SNP) | VAF 299/602 reads (50%) | catalogued as COSV54250603; called by muse, mutect2, varscan2
- TRIP13 | c.507C>A p.I169= | Silent (SNP) | VAF 9/200 reads (5%) | catalogued as COSV99386477; called by muse, mutect2
